Somatic mutation profile of tumor specimen 0DLLW5 from CCDI case PBBZBH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 8.3 years (3,026 days).
Specimen 0DLLW5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a94dba99-c65e-4e62-a392-cfd15a6bc685.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLLV0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f232bbaa-07b7-42af-b592-629ff59fe185

The open-access MAF lists 34 somatic variants for this specimen: 27 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 4, 5'UTR 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 546/1352 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.832C>A p.P278T | Missense Mutation (SNP) | VAF 268/279 reads (96%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: likely pathogenic / drug response; called by muse, mutect2, varscan2
- AKR7L | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 103/379 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101334360; called by muse, mutect2, varscan2
- COBL | c.153G>T p.L51F | Missense Mutation (SNP) | VAF 123/519 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99474191; called by muse, mutect2, varscan2
- COL5A2 | c.3352C>T p.R1118C | Missense Mutation (SNP) | VAF 161/1020 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1386081744, COSV66408575; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DISP2 | c.1969C>T p.R657W | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1337228419; called by muse, mutect2, varscan2
- FFAR1 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 4488/4571 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762735568; called by muse, mutect2, varscan2
- KHDRBS2 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 78/304 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs533736043, COSV99834554; called by muse, mutect2, varscan2
- KRT81 | c.1435G>A p.G479R | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.259); catalogued as rs150356449; called by muse, mutect2, varscan2
- OR10G8 | c.91G>T p.V31L | Missense Mutation (SNP) | VAF 118/558 reads (21%) | SIFT tolerated (0.87); PolyPhen benign (0.011); catalogued as COSV70908251; called by muse, mutect2, varscan2
- OR2G3 | c.885G>T p.K295N | Missense Mutation (SNP) | VAF 157/778 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV100180469; called by muse, mutect2, varscan2
- PFKFB1 | c.1092G>T p.K364N | Missense Mutation (SNP) | VAF 152/333 reads (46%) | PolyPhen benign (0.035); catalogued as COSV66627873; called by muse, mutect2, varscan2
- STAB2 | c.5350G>A p.D1784N | Missense Mutation (SNP) | VAF 201/881 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs147807697, COSV66335384; called by muse, mutect2, varscan2
- ZNF276 | c.620C>T p.A207V (on ENST00000443381 / NM_001113525.2; = p.A132V on NM_152287.4) | Missense Mutation (SNP) | VAF 71/350 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57068698; called by muse, mutect2, varscan2
- ZNF528 | c.1155A>T p.E385D | Missense Mutation (SNP) | VAF 34/594 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV64619960; called by muse, mutect2
- ZNF598 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 60/253 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747567735, COSV70910202, COSV70911672; called by muse, mutect2, varscan2
- BROX | c.191A>G p.Y64C | Missense Mutation (SNP) | VAF 207/877 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CABIN1 | c.1297T>C p.S433P | Missense Mutation (SNP) | VAF 97/341 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSN2 | c.329C>A p.T110N | Missense Mutation (SNP) | VAF 170/748 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DDX4 | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 247/920 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MAP3K1 | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 187/821 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NMBR | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 138/531 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PJA1 | c.1577C>G p.A526G (on ENST00000361478 / NM_145119.4; = p.A338G on NM_022368.5) | Missense Mutation (SNP) | VAF 79/158 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZNF181 | c.60G>C p.W20C | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.013); called by mutect2, varscan2
- ZNF181 | c.133G>C p.G45R | Missense Mutation (SNP) | VAF 67/484 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF181 | c.1063G>T p.G355* | Nonsense Mutation (SNP) | VAF 90/536 reads (17%) | called by muse, mutect2, varscan2
- ZNF598 | c.1477G>A p.V493M | Missense Mutation (SNP) | VAF 114/226 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCL1 | c.168C>T p.I56= | Silent (SNP) | VAF 118/308 reads (38%) | called by muse, mutect2, varscan2
- LRFN1 | c.1602C>T p.G534= | Silent (SNP) | VAF 40/113 reads (35%) | called by muse, mutect2, varscan2
- MUC12 | c.8007C>T p.S2669= (on ENST00000379442; = p.S2526= on NM_001164462.1) | Silent (SNP) | VAF 35/689 reads (5%) | catalogued as rs527834294, COSV65198477; called by muse, mutect2
- OR2A25 | c.114G>C p.L38= | Silent (SNP) | VAF 61/289 reads (21%) | called by muse, mutect2, varscan2
- CD99 | c.476-4794G>T | Intron (SNP) | VAF 24/395 reads (6%) | catalogued as COSV66989505; called by muse, mutect2
- PPL | c.-20C>T | 5'UTR (SNP) | VAF 36/80 reads (45%) | called by muse, mutect2, varscan2
- RTL4 | c.-92C>G | 5'UTR (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
